Somatic mutation profile of tumor specimen TCGA-D8-A1JA-01A (aliquot TCGA-D8-A1JA-01A-11D-A13L-09) from TCGA case TCGA-D8-A1JA, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 60.0 years (21,918 days).
Specimen TCGA-D8-A1JA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 998e75ff-dff9-4c53-b8a1-222bfad7ca50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JA-10A (Blood Derived Normal), aliquot TCGA-D8-A1JA-10A-01W-A14R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0644d27-a598-467b-bdb9-1af921fef6e8

The open-access MAF lists 948 somatic variants for this specimen: 706 protein-altering or splice-affecting, 222 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 619, Silent 222, Nonsense Mutation 64, Intron 10, Splice Site 10, Frame Shift Del 5, 5'UTR 3, RNA 3, In Frame Del 3, Translation Start Site 2, Splice Region 2, 3'UTR 2.

Variants (750 of 948; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FKTN | c.1173-1G>C p.X391_splice | Splice Site (SNP) | VAF 39/104 reads (38%) | catalogued as rs557699482, COSV56308259; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.4393G>C p.E1465Q | Missense Mutation (SNP) | VAF 77/197 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV52218564; called by muse, mutect2, varscan2
- ABCA10 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs111474594, COSV52218576; called by muse, mutect2, varscan2
- ABCA12 | c.4510G>A p.E1504K (on ENST00000272895 / NM_173076.3; = p.E1186K on NM_015657.3) | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV55950135; called by muse, mutect2, varscan2
- ABCA13 | c.6740C>G p.S2247* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV70026012; called by muse, mutect2, varscan2
- ABCA4 | c.5475C>G p.F1825L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV64671238, COSV64673632; called by muse, mutect2, varscan2
- ABCB1 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); catalogued as rs139611979; called by muse, mutect2, varscan2
- ABCB11 | c.3904G>T p.E1302* | Nonsense Mutation (SNP) | VAF 58/142 reads (41%) | catalogued as CM081484, COSV55585825; called by muse, mutect2, varscan2
- ABCB4 | c.2354G>A p.R785K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55932345; called by muse, mutect2, varscan2
- ABCB4 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as CM105795, COSV55932360; called by muse, mutect2, varscan2
- ABCC10 | c.2402G>A p.R801H (on ENST00000372530 / NM_001198934.2; = p.R773H on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs145182782; called by muse, mutect2, varscan2
- ABCC8 | c.990G>C p.E330D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV56846680; called by muse, varscan2
- ABCC9 | c.1287C>G p.F429L | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV53963400, COSV53967641; called by muse, mutect2, varscan2
- ABHD8 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56044094; called by muse, mutect2, varscan2
- ABTB2 | c.1970C>G p.S657* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV54384355, COSV54389393; called by muse, mutect2, varscan2
- ACER2 | c.819G>C p.K273N | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.376); catalogued as COSV100575897; called by muse, mutect2
- ADAM21 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50788856; called by muse, mutect2, varscan2
- ADAM28 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs777149299, COSV56097980; called by muse, mutect2, varscan2
- ADAM28 | c.1976C>G p.S659C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV56097996; called by muse, mutect2, varscan2
- ADAMTS14 | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV64599775, COSV64605755; called by muse, mutect2, varscan2
- ADAMTS7 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66306009; called by muse, mutect2, varscan2
- ADAMTS9 | c.3484T>A p.L1162I | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.16); catalogued as COSV55775455; called by muse, mutect2, varscan2
- ADH6 | c.1033C>G p.P345A | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV52955069; called by muse, mutect2, varscan2
- AGT | c.1052C>G p.S351C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV64183933; called by muse, mutect2, varscan2
- AHI1 | c.303G>C p.L101F | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.172); catalogued as COSV55623164; called by muse, mutect2, varscan2
- AHNAK2 | c.2775G>C p.K925N | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60908496; called by muse, mutect2, varscan2
- AK7 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as COSV50869277; called by muse, mutect2, varscan2
- AKAP6 | c.6634G>T p.A2212S | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.118); catalogued as COSV55205824; called by muse, mutect2, varscan2
- ALDH3A2 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 43/116 reads (37%) | catalogued as COSV51565673; called by muse, mutect2, varscan2
- ALMS1 | c.10213G>A p.D3405N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV52503438; called by muse, mutect2, varscan2
- ALOX12 | c.1781C>G p.S594* | Nonsense Mutation (SNP) | VAF 18/24 reads (75%) | catalogued as COSV52348656; called by muse, mutect2, varscan2
- ALPK2 | c.5297C>G p.S1766* | Nonsense Mutation (SNP) | VAF 85/123 reads (69%) | catalogued as COSV64490427; called by muse, mutect2, varscan2
- AMIGO3 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV57537593; called by muse, mutect2, varscan2
- AMOTL1 | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100504467, COSV58565049; called by muse, mutect2, varscan2
- ANGPT4 | c.336G>C p.L112F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV67920696; called by muse, mutect2, varscan2
- ANK2 | c.672G>C p.M224I | Missense Mutation (SNP) | VAF 99/229 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52147387; called by muse, mutect2, varscan2
- ANK2 | c.4657G>A p.E1553K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52147412, COSV52157115; called by muse, mutect2, varscan2
- ANK3 | c.7547C>G p.S2516C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.43); catalogued as COSV55045363; called by muse, mutect2, varscan2
- ANK3 | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55045368; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5290C>G p.Q1764E | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV51841008; called by muse, mutect2, varscan2
- ANKIB1 | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.387); catalogued as COSV56058735, COSV56058779; called by muse, mutect2, varscan2
- ANKMY1 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56030451; called by muse, mutect2, varscan2
- ANKRD49 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV100120165; called by muse, mutect2, varscan2
- ANKRD6 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60229023; called by muse, mutect2, varscan2
- ANO1 | c.1812G>C p.E604D | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.261); catalogued as COSV60281401; called by muse, mutect2, varscan2
- ANO6 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs745465915, COSV57657217; called by muse, mutect2, varscan2
- ANXA4 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.924); catalogued as COSV67848392; called by muse, mutect2, varscan2
- APBA1 | c.1418C>G p.S473* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV55222141; called by muse, varscan2
- APCDD1 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV62372059; called by muse, mutect2, varscan2
- APLP2 | c.992C>G p.S331C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); catalogued as rs1167109680, COSV53839081; called by mutect2, varscan2
- ARAP1 | c.3041C>A p.S1014Y (on ENST00000393609 / NM_001040118.2; = p.S769Y on NM_015242.4) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61992217; called by muse, mutect2
- ARAP2 | c.4870C>T p.R1624* | Nonsense Mutation (SNP) | VAF 38/57 reads (67%) | catalogued as rs868517624, COSV58282896; called by muse, mutect2, varscan2
- ARHGAP10 | c.759C>G p.I253M | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.202); catalogued as COSV60595254; called by muse, mutect2, varscan2
- ARHGAP24 | c.2070G>C p.E690D (on ENST00000395184 / NM_001025616.3; = p.E597D on NM_031305.3) | Missense Mutation (SNP) | VAF 67/109 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV51986850; called by muse, mutect2, varscan2
- ARHGAP29 | c.3682G>C p.E1228Q | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); catalogued as COSV53108754; called by muse, mutect2, varscan2
- ARHGAP31 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV51789438; called by muse, mutect2, varscan2
- ARHGEF11 | c.895G>C p.D299H | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV63810512; called by muse, mutect2, varscan2
- ARID1B | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV51649717; called by muse, mutect2, varscan2
- ARL3 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); catalogued as COSV53298957; called by muse, mutect2, varscan2
- ARSL | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66964845; called by muse, mutect2, varscan2
- ASAP1 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1212831384, COSV63044724, COSV63055109; called by muse, mutect2, varscan2
- ASH1L | c.7705G>C p.E2569Q (on ENST00000368346 / NM_001366177.2; = p.E2564Q on NM_018489.3) | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.702); catalogued as COSV64205696; called by muse, mutect2, varscan2
- ASPM | c.7473C>G p.F2491L | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as rs767778442, COSV54125105; called by muse, mutect2, varscan2
- ASTN1 | c.2869G>A p.E957K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV62490027, COSV62491543; called by muse, mutect2, varscan2
- ATP10A | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as rs201206599, COSV63512808; called by muse, mutect2, varscan2
- ATP2A3 | c.2595C>G p.I865M | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV59226411, COSV59233793; called by muse, mutect2, varscan2
- ATP2C1 | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV100146951, COSV60752897; called by muse, mutect2, varscan2
- ATRX | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV64869240, COSV64870408; called by muse, mutect2, varscan2
- AVEN | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as rs1567460464, COSV60732312; called by muse, mutect2, varscan2
- B3GNT7 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55005871; called by muse, mutect2, varscan2
- BAZ1A | c.1384G>C p.V462L | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV62409079; called by muse, mutect2, varscan2
- BBS9 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54157468; called by muse, mutect2, varscan2
- BMPER | c.442C>G p.H148D | Missense Mutation (SNP) | VAF 109/253 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.622); catalogued as COSV99779712, COSV99780801; called by muse, mutect2
- BPTF | c.4820C>G p.S1607C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.088); catalogued as COSV58831883; called by muse, mutect2, varscan2
- BRI3 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs772300526, COSV50054697; called by muse, mutect2, varscan2
- BRIP1 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as CM1512696, COSV51994417; called by muse, mutect2, varscan2
- BTK | c.1574G>C p.R525P | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as CM940199, CM950170, COSV58117568, COSV58123749; called by muse, mutect2, varscan2
- BTN3A3 | c.379T>C p.Y127H | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55070959; called by muse, mutect2, varscan2
- BUB1B | c.1691C>G p.S564* | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | catalogued as COSV55010048; called by muse, mutect2, varscan2
- BYSL | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as COSV57827836; called by muse, mutect2, varscan2
- C10orf120 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.49); catalogued as COSV61491640; called by muse, mutect2, varscan2
- C11orf49 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); catalogued as COSV53563377; called by muse, mutect2, varscan2
- C11orf80 | c.1547C>G p.S516* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as COSV60928100, COSV60928816; called by muse, mutect2, varscan2
- C12orf45 | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs371639910, COSV55012459; called by muse, mutect2, varscan2
- C19orf44 | c.1574G>C p.R525T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs375608776; called by muse, mutect2, varscan2
- C2orf78 | c.1958C>G p.S653C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV68516404, COSV68518717; called by muse, mutect2, varscan2
- C3orf20 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV53782632; called by muse, mutect2, varscan2
- C4orf17 | c.100C>G p.H34D | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58511400; called by muse, varscan2
- CA11 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50032756; called by muse, mutect2, varscan2
- CACNA1E | c.1680C>G p.F560L | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV100705784; called by muse, mutect2, varscan2
- CADM2 | c.833G>C p.G278A (on ENST00000407528 / NM_001167674.2; = p.G280A on NM_153184.4) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67358663; called by muse, mutect2, varscan2
- CALCOCO2 | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 56/705 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99363995; called by muse, mutect2
- CAP2 | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.119); catalogued as COSV57730192; called by muse, mutect2, varscan2
- CAPN11 | c.949C>G p.R317G | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV67236236; called by muse, mutect2, varscan2
- CAPN9 | c.62T>G p.I21S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99681255; called by muse, mutect2
- CAPN9 | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99681259; called by muse, mutect2
- CARD11 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV62754126; called by muse, mutect2, varscan2
- CARS2 | c.1209G>C p.K403N | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV57284179, COSV57286916; called by muse, mutect2, varscan2
- CASP7 | c.852G>C p.E284D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.141); catalogued as COSV61881074; called by muse, mutect2, varscan2
- CC2D1B | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV52558833; called by muse, mutect2, varscan2
- CCDC14 | c.2129C>T p.S710F (on ENST00000488653; = p.S662F on NM_022757.5) | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.146); catalogued as COSV59943038; called by muse, mutect2, varscan2
- CCDC146 | c.1064G>A p.R355K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.172); catalogued as rs964627375, COSV53544247; called by muse, mutect2, varscan2
- CCDC34 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 116/320 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.596); catalogued as COSV60820151, COSV60821631; called by muse, mutect2, varscan2
- CCDC39 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 114/334 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56479058; called by muse, mutect2, varscan2
- CCN1 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as COSV71704276; called by muse, mutect2, varscan2
- CD40 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64847524; called by muse, mutect2, varscan2
- CDCP1 | c.2404G>C p.E802Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV56103844; called by muse, mutect2, varscan2
- CDH12 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 120/308 reads (39%) | catalogued as COSV66389350; called by muse, mutect2, varscan2
- CDK5 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV52520616; called by muse, mutect2, varscan2
- CDK7 | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV56511965; called by muse, mutect2, varscan2
- CENPF | c.3821C>T p.S1274L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as rs746908378, COSV65272870; called by muse, mutect2, varscan2
- CENPL | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.123); catalogued as COSV61891472; called by muse, mutect2, varscan2
- CEP350 | c.2537T>G p.L846* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as COSV62599054; called by muse, mutect2, varscan2
- CEP350 | c.7645G>C p.E2549Q | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.124); catalogued as COSV62599063; called by muse, mutect2, varscan2
- CETN3 | c.-1_2del | Translation Start Site (DEL) | VAF 11/30 reads (37%) | catalogued as rs773424505; called by mutect2, pindel, varscan2
- CFAP44 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as COSV55608781; called by muse, mutect2, varscan2
- CFAP53 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 67/112 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV68351364, COSV68352986; called by muse, mutect2, varscan2
- CFAP54 | c.7420C>G p.Q2474E | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.9); PolyPhen benign (0.031); catalogued as COSV100733421; called by muse, mutect2
- CHD9 | c.3979G>C p.D1327H | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54607912, COSV54613414; called by muse, mutect2, varscan2
- CHST4 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as rs570836136, COSV58296533; called by muse, mutect2, varscan2
- CHUK | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV64917253; called by muse, mutect2, varscan2
- CKAP5 | c.42G>C p.Q14H | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56364416; called by muse, mutect2, varscan2
- CLCNKB | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as COSV65159709; called by muse, mutect2, varscan2
- CLEC4M | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1299563695, COSV50216865, COSV99940363; called by muse, mutect2, varscan2
- CLSTN1 | c.2896G>A p.A966T (on ENST00000377298 / NM_001009566.3; = p.A956T on NM_014944.4) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs749257979, COSV63127214; called by muse, mutect2, varscan2
- CLUAP1 | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as rs1567445188, COSV57087517; called by muse, mutect2, varscan2
- CNOT1 | c.4828C>T p.Q1610* | Nonsense Mutation (SNP) | VAF 30/68 reads (44%) | catalogued as COSV55313344; called by muse, mutect2, varscan2
- CNPY2 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV56263773; called by muse, mutect2, varscan2
- CNTN1 | c.2689G>C p.E897Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV61636485, COSV61643751; called by muse, mutect2, varscan2
- CNTN4 | c.2788G>C p.E930Q | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61868242; called by muse, mutect2, varscan2
- CNTNAP5 | c.2451C>G p.F817L | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV70474108; called by muse, mutect2, varscan2
- COL11A1 | c.5295G>C p.K1765N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV62173804; called by muse, mutect2, varscan2
- COL13A1 | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); catalogued as COSV62567160; called by muse, mutect2, varscan2
- COL13A1 | c.1959G>A p.M653I (on ENST00000398978 / NM_001130103.2; = p.M581I on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV62567174; called by muse, mutect2, varscan2
- COL5A2 | c.3293G>C p.G1098A | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66407310; called by muse, mutect2, varscan2
- COL6A2 | c.2430G>C p.Q810H | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.28); PolyPhen benign (0.155); catalogued as COSV55999527; called by muse, mutect2, varscan2
- COMMD4 | c.222C>A p.F74L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51190183; called by muse, mutect2, varscan2
- COX15 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as COSV50011902; called by muse, mutect2, varscan2
- CPEB1 | c.1510G>C p.E504Q (on ENST00000617958; = p.E439Q on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV55616935, COSV55617303; called by muse, mutect2
- CPED1 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.551); catalogued as COSV59997645; called by muse, mutect2, varscan2
- CPED1 | c.3042C>G p.I1014M | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59997654, COSV60012081; called by muse, mutect2, varscan2
- CRACR2B | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1362845113, COSV58989118; called by muse, mutect2, varscan2
- CRYGD | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV52204832; called by muse, mutect2, varscan2
- CSF3R | c.2139C>G p.N713K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV58963590; called by muse, mutect2, varscan2
- CSMD1 | c.6425G>A p.R2142K (on ENST00000520002; = p.R2141K on NM_033225.6) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); catalogued as COSV59280345, COSV59284885; called by muse, mutect2, varscan2
- CSMD1 | c.3083C>T p.S1028L (on ENST00000520002; = p.S1027L on NM_033225.6) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59284916; called by muse, mutect2, varscan2
- CSPP1 | c.2173C>G p.L725V (on ENST00000676605; = p.L684V on NM_024790.6) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.033); catalogued as COSV51580548, COSV51581619; called by muse, mutect2, varscan2
- CTNND1 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.913); catalogued as rs770665127, COSV62382269; called by muse, mutect2, varscan2
- CTTNBP2 | c.924G>C p.Q308H | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370017291; called by muse, mutect2, varscan2
- CWH43 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs1193026349, COSV56936152; called by muse, varscan2
- CXCR3 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs367701341, COSV101031597, COSV101031754; called by muse, mutect2, varscan2
- CYP4A11 | c.1450C>G p.P484A | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.208); catalogued as rs1267000192, COSV60222232; called by muse, varscan2
- CYP4F3 | c.1467C>G p.F489L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55407366, COSV55412951; called by muse, mutect2, varscan2
- DCAF6 | c.1258C>G p.Q420E | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.022); catalogued as COSV56575308; called by muse, mutect2, varscan2
- DCTN4 | c.1168G>C p.D390H | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV69781755; called by muse, mutect2, varscan2
- DDX20 | c.762G>C p.L254F | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63830793; called by muse, mutect2, varscan2
- DDX31 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV60134336; called by muse, mutect2, varscan2
- DDX3X | c.81G>C p.Q27H | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); catalogued as COSV67863128; called by muse, mutect2, varscan2
- DDX49 | c.798G>A p.M266I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV53229605; called by muse, mutect2, varscan2
- DDX6 | c.1104G>C p.M368I | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50587686; called by muse, mutect2, varscan2
- DEFB125 | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66703062, COSV66703499; called by muse, mutect2, varscan2
- DEFB125 | c.205G>C p.A69P | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV66703065; called by muse, mutect2, varscan2
- DEK | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.224); catalogued as COSV55236610, COSV55238166; called by muse, mutect2, varscan2
- DGKB | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.412); catalogued as COSV51763573; called by muse, mutect2, varscan2
- DGKD | c.896C>T p.T299M (on ENST00000264057 / NM_152879.3; = p.T255M on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs758673209, COSV51033756; called by muse, mutect2, varscan2
- DGKI | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55937587, COSV99933643; called by muse, mutect2, varscan2
- DHPS | c.147C>G p.F49L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52951591, COSV52951708, COSV52952106; called by muse, mutect2, varscan2
- DLGAP5 | c.992G>A p.R331K | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.151); catalogued as COSV55962129; called by muse, mutect2, varscan2
- DMD | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 20/154 reads (13%) | catalogued as COSV55855325; called by muse, mutect2, varscan2
- DMXL2 | c.1775C>G p.S592* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV51841174; called by muse, mutect2, varscan2
- DNA2 | c.1826C>G p.S609C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV64427487; called by muse, mutect2, varscan2
- DNAH11 | c.9472G>A p.E3158K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768698591, COSV60941383, COSV60974803; called by muse, mutect2, varscan2
- DNAH3 | c.7551C>G p.I2517M | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV54505211; called by muse, mutect2, varscan2
- DNAH7 | c.9768G>C p.Q3256H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV56753166; called by muse, mutect2, varscan2
- DNAJC1 | c.1644G>C p.K548N | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV65409094; called by muse, mutect2, varscan2
- DNMBP | c.1478G>A p.R493K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV60620893; called by muse, mutect2, varscan2
- DRC3 | c.201G>C p.L67F | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58261795; called by muse, mutect2, varscan2
- DUOX2 | c.4105G>A p.E1369K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV101199925; called by muse, mutect2, varscan2
- DUSP10 | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV60456659; called by muse, mutect2, varscan2
- DYNC2H1 | c.10574G>A p.R3525Q | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs760508083, COSV62087018; called by muse, mutect2, varscan2
- ECD | c.1422-1G>C p.X474_splice | Splice Site (SNP) | VAF 48/105 reads (46%) | catalogued as COSV65898697; called by muse, mutect2, varscan2
- EDC3 | c.613G>C p.D205H | Missense Mutation (SNP) | VAF 138/238 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59339202; called by muse, mutect2, varscan2
- EEF2KMT | c.116G>C p.R39T | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV69863596; called by muse, mutect2, varscan2
- EFCAB5 | c.1699G>C p.E567Q | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV57926375; called by muse, mutect2, varscan2
- EFEMP2 | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV57259211; called by muse, mutect2, varscan2
- EIF3I | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV59083983; called by muse, mutect2, varscan2
- ELMO1 | c.156G>C p.Q52H | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV60296092; called by muse, mutect2, varscan2
- EMILIN1 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53153384; called by muse, mutect2, varscan2
- EML1 | c.2277C>G p.D759E | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV51741839; called by muse, mutect2, varscan2
- ENPP4 | c.621G>C p.L207F | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58088251; called by muse, mutect2, varscan2
- ENTHD1 | c.1029C>G p.I343M | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV57317497; called by muse, mutect2, varscan2
- ENTPD7 | c.1377C>G p.F459L | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs1254834466, COSV65111960; called by muse, mutect2, varscan2
- EPG5 | c.6828G>C p.M2276I | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs1487918314, COSV56344924; called by muse, mutect2, varscan2
- EPHA7 | c.1472C>G p.S491* | Nonsense Mutation (SNP) | VAF 44/115 reads (38%) | catalogued as COSV65177758; called by muse, mutect2, varscan2
- EPHB3 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100383341; called by muse, mutect2
- ERC2 | c.2407G>C p.E803Q | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV55602734, COSV55615907; called by muse, mutect2, varscan2
- ERCC6 | c.4034C>T p.S1345L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV63387969; called by muse, mutect2, varscan2
- EXOC2 | c.11C>G p.S4* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100033332, COSV57861489; called by muse, mutect2, varscan2
- FAAH | c.576C>G p.F192L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1317306713, COSV54543151; called by muse, mutect2, varscan2
- FABP7 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV62956398, COSV62956788; called by muse, mutect2, varscan2
- FABP9 | c.191C>G p.S64C | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV66911406; called by muse, mutect2, varscan2
- FAM111B | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV59111134; called by muse, mutect2, varscan2
- FAM219B | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV62946690; called by muse, mutect2, varscan2
- FBH1 | c.2790C>G p.I930M (on ENST00000362091 / NM_178150.3; = p.I981M on NM_032807.4) | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV62981678; called by muse, mutect2, varscan2
- FBN1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1232880706, COSV57309992; called by muse, mutect2, varscan2
- FBXO3 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV55765064; called by muse, mutect2, varscan2
- FGF10 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.319); catalogued as rs1158466327, COSV52932133, COSV52939185; called by muse, mutect2, varscan2
- FGFR2 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV60640557; called by muse, mutect2, varscan2
- FHIT | c.191G>C p.R64T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV59285617; called by muse, mutect2, varscan2
- FHOD1 | c.1587C>G p.I529M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV50758704, COSV50766466; called by muse, mutect2, varscan2
- FKBP8 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV55891178; called by muse, mutect2, varscan2
- FLAD1 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52695918, COSV52696358, COSV99422625; called by muse, mutect2, varscan2
- FLT3LG | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.141); catalogued as rs367551792, COSV52618285; called by muse, mutect2, varscan2
- FMR1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV54422025; called by muse, mutect2, varscan2
- FNDC7 | c.2197G>C p.E733Q | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV54750973, COSV54752595; called by muse, mutect2, varscan2
- FNTB | c.95G>C p.R32P | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as COSV99862875, COSV99863151; called by muse, mutect2, varscan2
- FOCAD | c.4551G>T p.M1517I | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs772465371, COSV100620765; called by muse, mutect2
- FOCAD | c.5164C>T p.H1722Y | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.684); catalogued as COSV58093879; called by muse, mutect2, varscan2
- FRAS1 | c.5311G>C p.E1771Q | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as COSV53591694; called by muse, mutect2, varscan2
- FRMD3 | c.894G>A p.W298* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV58455307; called by muse, mutect2, varscan2
- FTSJ3 | c.2382G>C p.E794D | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV63789377; called by muse, mutect2, varscan2
- FUT11 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV59540128; called by muse, mutect2, varscan2
- FYB2 | c.1477G>C p.D493H | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58583059; called by muse, mutect2, varscan2
- FYCO1 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56113776; called by muse, mutect2, varscan2
- FZD6 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62470685; called by muse, mutect2, varscan2
- GABRA4 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV51922903; called by muse, mutect2, varscan2
- GABRB1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV54971566, COSV54996280; called by muse, mutect2, varscan2
- GABRG1 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54950325, COSV54957627; called by muse, mutect2, varscan2
- GALNT5 | c.2518G>C p.E840Q | Missense Mutation (SNP) | VAF 112/265 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52035948; called by muse, mutect2, varscan2
- GAPVD1 | c.3764G>C p.R1255T (on ENST00000394104; = p.R1264T on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV52920573; called by muse, mutect2, varscan2
- GAS2L3 | c.1612C>G p.Q538E | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV57156068; called by muse, mutect2, varscan2
- GFPT2 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs757899837, COSV53806552; called by muse, mutect2, varscan2
- GGPS1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51396893; called by muse, mutect2, varscan2
- GMNN | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57776566; called by muse, mutect2, varscan2
- GNAZ | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV50736983; called by muse, mutect2, varscan2
- GON4L | c.6625G>A p.E2209K | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV55187518; called by muse, mutect2, varscan2
- GPATCH8 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 31/49 reads (63%) | catalogued as COSV59193284; called by muse, mutect2, varscan2
- GPR42 | c.663G>C p.R221S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV71995001; called by muse, mutect2, varscan2
- GRM6 | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV51434523, COSV51444361; called by muse, mutect2, varscan2
- GRTP1 | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 19/26 reads (73%) | catalogued as rs144216849; called by muse, mutect2, varscan2
- GSTA1 | c.30C>G p.F10L | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV58014534; called by muse, mutect2, varscan2
- GSTA5 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 95/273 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV52861334, COSV52863920; called by muse, mutect2, varscan2
- GTF3C1 | c.5230G>C p.E1744Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.314); catalogued as COSV62239056; called by muse, mutect2, varscan2
- H4C4 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs773088974, COSV61590715; called by muse, mutect2, varscan2
- HAS2 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58262207, COSV58263921; called by muse, mutect2, varscan2
- HDX | c.563C>G p.S188* | Nonsense Mutation (SNP) | VAF 59/166 reads (36%) | catalogued as COSV52973280, COSV52983926; called by muse, mutect2, varscan2
- HERC1 | c.7798G>C p.V2600L | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV71246027; called by muse, mutect2, varscan2
- HERC1 | c.2265G>C p.E755D | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV71246028; called by muse, mutect2, varscan2
- HLA-B | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as CM015109, COSV101318127, COSV101318294, COSV69522021; called by muse, mutect2
- HMCES | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV101077257, COSV67300127; called by muse, mutect2, varscan2
- HMG20A | c.616-1G>C p.X206_splice | Splice Site (SNP) | VAF 41/132 reads (31%) | catalogued as COSV60311213, COSV60311424; called by muse, mutect2, varscan2
- HMGCLL1 | c.139C>G p.Q47E | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV51440856; called by muse, mutect2, varscan2
- HNRNPH3 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as rs756561116, COSV56261815; called by muse, mutect2, varscan2
- HORMAD1 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 153/504 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV59270344; called by muse, mutect2, varscan2
- HSPA4L | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs759610355, COSV56543810; called by muse, mutect2, varscan2
- HSPA5 | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.982); catalogued as COSV52334131; called by muse, mutect2, varscan2
- HTATIP2 | c.413C>G p.S138* | Nonsense Mutation (SNP) | VAF 70/153 reads (46%) | catalogued as COSV70041013, COSV70041064; called by muse, mutect2, varscan2
- HTR1D | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV58447323, COSV58449474; called by muse, mutect2, varscan2
- HTR3A | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV55468131; called by muse, mutect2, varscan2
- HUS1B | c.796C>G p.Q266E | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV57861496; called by muse, mutect2, varscan2
- HUWE1 | c.10130C>G p.S3377* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV53335540; called by muse, mutect2, varscan2
- HVCN1 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.311); catalogued as rs554508796, COSV54371239; called by muse, mutect2, varscan2
- IARS2 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 28/92 reads (30%) | catalogued as COSV56957741; called by muse, mutect2, varscan2
- ICE1 | c.5320C>G p.Q1774E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV56819516, COSV56833659; called by muse, mutect2, varscan2
- IDI1 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67281416, COSV67281668; called by muse, mutect2, varscan2
- IFNA17 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 100/1532 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs746439830, COSV101303488; called by muse, mutect2
- IFNA5 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 104/1882 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV52387129; called by muse, mutect2
- IFNA6 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 116/1881 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101207034, COSV66506566; called by muse, mutect2
- IFT122 | c.566G>A p.R189Q (on ENST00000348417 / NM_052989.3; = p.R240Q on NM_052985.4) | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs769736492, COSV56200112; called by muse, mutect2, varscan2
- IL22 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV60159729; called by muse, mutect2, varscan2
- ILF3 | c.1164G>C p.K388N | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51554533; called by muse, mutect2, varscan2
- INKA2 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV61877112; called by muse, mutect2, varscan2
- INPP5D | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 23/37 reads (62%) | catalogued as COSV64035510; called by muse, mutect2, varscan2
- INSIG2 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs760931206, COSV55521895; called by muse, mutect2, varscan2
- IQGAP1 | c.2844G>A p.M948I | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV51581739, COSV51590427; called by muse, mutect2, varscan2
- IQGAP1 | c.3315G>C p.Q1105H | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV51581756; called by muse, mutect2, varscan2
- IRF6 | c.899G>C p.R300T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV65418722, COSV65419361; called by muse, mutect2, varscan2
- IRF9 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60702716, COSV60704258; called by muse, mutect2, varscan2
- ISG20L2 | c.426G>C p.Q142H | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.205); catalogued as COSV57459451; called by muse, mutect2, varscan2
- ITGB2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs374031101; called by muse, mutect2, varscan2
- ITIH3 | c.2564G>A p.R855K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV56571597; called by muse, mutect2, varscan2
- ITPRID2 | c.2843C>T p.S948L | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV100237891, COSV57469709; called by muse, mutect2, varscan2
- JADE3 | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as COSV54464474; called by muse, mutect2, varscan2
- JAK2 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV101081332; called by muse, mutect2, varscan2
- JMJD1C | c.5338G>C p.D1780H | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59512995; called by muse, mutect2, varscan2
- JMJD1C | c.4507G>A p.E1503K | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.304); catalogued as COSV59513008; called by muse, mutect2, varscan2
- KALRN | c.3436A>T p.I1146F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53753906; called by muse, mutect2, varscan2
- KAT6A | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55902986; called by muse, mutect2, varscan2
- KCNC2 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54362974; called by muse, mutect2, varscan2
- KCNK10 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as rs201294051; called by muse, mutect2, varscan2
- KCNK18 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.826); catalogued as COSV57971014, COSV57973091, COSV57973363; called by muse, mutect2, varscan2
- KCNK2 | c.1207G>A p.E403K (on ENST00000444842 / NM_001017425.3; = p.E388K on NM_014217.4) | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); catalogued as COSV67203463; called by muse, mutect2, varscan2
- KDM3A | c.2007C>G p.I669M | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57218386; called by muse, mutect2, varscan2
- KDM3B | c.3981G>C p.K1327N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV58688215; called by muse, mutect2, varscan2
- KDM4D | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58633666, COSV58635052; called by muse, mutect2, varscan2
- KDM5A | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV66990474, COSV66994298; called by muse, mutect2, varscan2
- KIAA0586 | c.445C>G p.Q149E (on ENST00000619416 / NM_001244190.2; = p.Q164E on NM_014749.5) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as COSV54171528; called by muse, mutect2, varscan2
- KIAA1210 | c.3636G>C p.K1212N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV68175633; called by muse, mutect2, varscan2
- KIAA1614 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV62550403; called by muse, mutect2
- KIAA2026 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV67353472; called by muse, mutect2, varscan2
- KIF13A | c.3550G>C p.D1184H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV52443544; called by muse, mutect2, varscan2
- KIF21B | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100145271; called by muse, mutect2
- KIF27 | c.1367C>G p.S456* | Nonsense Mutation (SNP) | VAF 45/107 reads (42%) | catalogued as COSV52825373, COSV52827915; called by muse, mutect2, varscan2
- KLHL14 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 63/95 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63830724; called by muse, mutect2, varscan2
- KLK15 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs571715638, COSV56825833, COSV56826507; called by muse, mutect2
- KMT2E | c.68C>G p.S23* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV57569842; called by muse, mutect2, varscan2
- KRIT1 | c.544C>G p.P182A | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.98); catalogued as rs1409604560, COSV60666937, COSV60668239; called by muse, mutect2, varscan2
- KRTAP21-1 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 100/119 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV58645893; called by muse, mutect2, varscan2
- KRTAP8-1 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 40/43 reads (93%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as COSV61597738; called by muse, mutect2, varscan2
- LCK | c.1419G>A p.M473I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV60738692; called by muse, mutect2, varscan2
- LCOR | c.4207G>A p.E1403K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.933); catalogued as COSV53714539; called by muse, mutect2, varscan2
- LEXM | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV64022091; called by muse, mutect2, varscan2
- LIX1L | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377468487; called by muse, mutect2, varscan2
- LMAN2 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57423783; called by muse, mutect2, varscan2
- LMTK2 | c.4421C>G p.S1474C | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51990899; called by muse, mutect2, varscan2
- LPA | c.3061G>C p.E1021Q | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.542); catalogued as COSV60297374; called by muse, mutect2, varscan2
- LRATD1 | c.836G>C p.R279P | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.425); catalogued as rs756473710, COSV54472299, COSV54473759; called by muse, mutect2, varscan2
- LRCH2 | c.1120C>G p.Q374E | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.931); catalogued as COSV57746395; called by muse, mutect2, varscan2
- LRCH2 | c.392G>A p.W131* | Nonsense Mutation (SNP) | VAF 23/75 reads (31%) | catalogued as COSV57746416; called by muse, mutect2, varscan2
- LRCH3 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58389215; called by muse, mutect2, varscan2
- LRMDA | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV65269011; called by muse, mutect2, varscan2
- LRP5 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1270099780, COSV53711618; called by muse, mutect2, varscan2
- LRRC41 | c.1191G>C p.K397N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV58438989; called by muse, mutect2, varscan2
- LRRC7 | c.973C>G p.Q325E (on ENST00000651989 / NM_001370785.2; = p.Q292E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV50413621; called by muse, mutect2, varscan2
- LRRTM4 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.301); catalogued as COSV69139072; called by muse, mutect2, varscan2
- LTBP1 | c.2221C>T p.H741Y (on ENST00000404816 / NM_206943.4; = p.H415Y on NM_000627.4) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.651); catalogued as COSV63180605; called by muse, mutect2, varscan2
- LTF | c.513C>G p.F171L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV51605813; called by muse, mutect2, varscan2
- LYRM2 | c.187-3C>G | Splice Region (SNP) | VAF 8/28 reads (29%) | catalogued as COSV60229030; called by muse, mutect2, varscan2
- LYSMD1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV64423144; called by muse, mutect2, varscan2
- LYSMD3 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100270397, COSV60056512; called by muse, mutect2, varscan2
- MAGED1 | c.666del p.D222Efs*22 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as COSV100431331, COSV58514586; called by mutect2, pindel, varscan2
- MAGI1 | c.3358G>C p.D1120H (on ENST00000402939 / NM_001033057.2; = p.D1149H on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV58315377; called by muse, mutect2, varscan2
- MAMDC2 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 93/253 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65856709; called by muse, mutect2, varscan2
- MANBA | c.1810C>T p.Q604* (on ENST00000642252; = p.Q558* on NM_005908.4) | Nonsense Mutation (SNP) | VAF 65/107 reads (61%) | catalogued as COSV56963009; called by muse, mutect2, varscan2
- MAP3K5 | c.2392C>T p.Q798* | Nonsense Mutation (SNP) | VAF 56/152 reads (37%) | catalogued as COSV62887244; called by muse, mutect2, varscan2
- MAP9 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT tolerated (0.36); PolyPhen benign (0.099); catalogued as rs767984897, COSV60903674; called by muse, mutect2, varscan2
- MARCHF5 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV62768911; called by muse, varscan2
- MARCHF5 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62768920; called by muse, varscan2
- MARCHF5 | c.185G>C p.R62T | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV62768928; called by muse, mutect2, varscan2
- MAS1L | c.702C>G p.I234M | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.538); catalogued as COSV65808519; called by muse, mutect2, varscan2
- MAST2 | c.2191G>C p.E731Q | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV63616238; called by muse, mutect2, varscan2
- MCF2L2 | c.1777-1G>C p.X593_splice | Splice Site (SNP) | VAF 4/9 reads (44%) | catalogued as COSV58475415; called by muse, mutect2, varscan2
- MCTP2 | c.2306C>G p.S769* | Nonsense Mutation (SNP) | VAF 70/264 reads (27%) | catalogued as COSV100752603; called by muse, mutect2, varscan2
- MDM1 | c.1520C>G p.S507* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV57444616; called by muse, mutect2, varscan2
- MDN1 | c.13855G>C p.D4619H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV65516829, COSV65517541; called by muse, mutect2, varscan2
- ME3 | c.724C>G p.L242V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV60164245; called by muse, mutect2, varscan2
- MECOM | c.64C>T p.R22C (on ENST00000468789 / NM_001105078.4; = p.R210C on NM_004991.4) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs149892422, COSV52960097; called by muse, mutect2, varscan2
- MEGF11 | c.2628G>C p.Q876H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV56545229; called by muse, mutect2, varscan2
- MEIS2 | c.245G>A p.G82E (on ENST00000561208 / NM_170675.5; = p.G69E on NM_002399.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV54931725; called by muse, mutect2, varscan2
- MFAP1 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 95/206 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as COSV51038398, COSV51040424; called by muse, mutect2, varscan2
- MFHAS1 | c.1473C>A p.F491L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99360030; called by muse, mutect2
- MFSD9 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.042); catalogued as rs762045089, COSV51492729, COSV99302119, COSV99302265; called by muse, mutect2, varscan2
- MINDY1 | c.1273C>G p.Q425E | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.501); catalogued as COSV56497723; called by muse, mutect2, varscan2
- MIOS | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60767110; called by muse, mutect2, varscan2
- MIS18BP1 | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV60369237, COSV60373403; called by muse, mutect2, varscan2
- MMP15 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54678776; called by muse, mutect2, varscan2
- MPP1 | c.1364G>A p.S455N | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs782458500, COSV101054039; called by muse, mutect2, varscan2
- MR1 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV51579890; called by muse, mutect2, varscan2
- MRC2 | c.3460G>A p.E1154K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs775932154, COSV57636903; called by muse, mutect2, varscan2
- MRPL13 | c.118C>G p.Q40E | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV59961082; called by muse, mutect2, varscan2
- MRPL47 | c.273G>C p.R91S | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52019447; called by muse, mutect2, varscan2
- MTCH2 | c.645G>C p.M215I | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV56766491; called by muse, mutect2, varscan2
- MTHFD1L | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV66208175; called by muse, mutect2, varscan2
- MTRR | c.917C>G p.S306* (on ENST00000264668; = p.S279* on NM_002454.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/75 reads (36%) | catalogued as COSV52941844; called by muse, mutect2, varscan2
- MUC16 | c.16656C>G p.F5552L | Missense Mutation (SNP) | VAF 119/324 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.135); catalogued as COSV67446999; called by muse, mutect2, varscan2
- MUC17 | c.11957C>T p.S3986L | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); catalogued as rs1562819680, COSV100073438; called by muse, mutect2, varscan2
- MUC17 | c.12259G>C p.E4087Q | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.16); catalogued as COSV60280909; called by muse, mutect2, varscan2
- MXRA5 | c.5716G>C p.E1906Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.562); catalogued as COSV54224691; called by muse, mutect2, varscan2
- MYCBP2 | c.3532G>C p.E1178Q (on ENST00000357337; = p.E1216Q on NM_015057.5) | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.932); catalogued as COSV62011006; called by muse, mutect2, varscan2
- MYH11 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55543785, COSV55545327; called by muse, mutect2, varscan2
- MYH13 | c.2415C>G p.F805L | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52821424, COSV52829121; called by muse, mutect2, varscan2
- MYL6 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as COSV52878315; called by muse, mutect2, varscan2
- MYO10 | c.5736G>C p.W1912C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57017151; called by muse, mutect2, varscan2
- MYO16 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV51778632; called by muse, mutect2, varscan2
- MYO3B | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 43/105 reads (41%) | catalogued as COSV58695073; called by muse, mutect2, varscan2
- MYO3B | c.1442C>G p.S481* | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | catalogued as COSV58695092; called by muse, mutect2, varscan2
- MYO5A | c.3541G>T p.E1181* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV62556921; called by muse, mutect2, varscan2
- NAA25 | c.1545C>G p.I515M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.541); catalogued as COSV55702227; called by muse, mutect2, varscan2
- NAALAD2 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV58958873; called by muse, mutect2, varscan2
- NAIF1 | c.132G>C p.K44N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66089880; called by muse, mutect2, varscan2
- NAP1L2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.679); catalogued as COSV65172207; called by muse, mutect2, varscan2
- NAV1 | c.2558C>G p.S853* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV55214278; called by muse, mutect2, varscan2
- NCOR1 | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 54/80 reads (68%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV51962135, COSV51969757; called by muse, mutect2, varscan2
- NDNF | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as rs1325079912, COSV101113264; called by muse, mutect2
- NDST1 | c.2016C>G p.F672L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.108); catalogued as COSV55785071; called by muse, mutect2, varscan2
- NDUFV3 | c.302C>G p.S101* (on ENST00000340344 / NM_001001503.2; = p.S466* on NM_021075.4) | Nonsense Mutation (SNP) | VAF 82/107 reads (77%) | catalogued as COSV61086993; called by muse, mutect2, varscan2
- NECTIN2 | c.909C>A p.F303L | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52975972; called by muse, mutect2, varscan2
- NEUROD6 | c.68G>C p.R23T | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as COSV51770132; called by muse, mutect2, varscan2
- NFIA | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV64533990; called by muse, mutect2, varscan2
- NFX1 | c.1911C>G p.F637L | Missense Mutation (SNP) | VAF 79/123 reads (64%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV59308389, COSV59309568; called by muse, mutect2, varscan2
- NIN | c.5731G>C p.E1911Q (on ENST00000382041 / NM_182946.1; = p.E1198Q on NM_016350.4) | Missense Mutation (SNP) | VAF 89/225 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55380993; called by muse, mutect2, varscan2
- NINL | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99626582; called by muse, mutect2
- NIP7 | c.247G>C p.V83L | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV54741753, COSV54743090; called by muse, mutect2, varscan2
- NKAP | c.1167G>C p.E389D | Missense Mutation (SNP) | VAF 85/212 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57629271; called by muse, mutect2, varscan2
- NMT2 | c.1415G>C p.G472A | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65381453; called by muse, mutect2, varscan2
- NOD1 | c.2629C>G p.Q877E | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV56110872; called by muse, mutect2, varscan2
- NOP14 | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 93/152 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV58624060; called by muse, mutect2, varscan2
- NPFFR2 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs150557185; called by muse, mutect2, varscan2
- NPR1 | c.2388G>C p.Q796H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.021); catalogued as COSV64117307; called by muse, mutect2, varscan2
- NR1D2 | c.1221G>T p.M407I | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as COSV56990734; called by muse, mutect2, varscan2
- NRDE2 | c.1792G>C p.D598H | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1471302889, COSV62962220; called by muse, mutect2, varscan2
- NUMA1 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100706705; called by muse, mutect2
- NUP107 | c.2088G>A p.M696I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV57493014; called by muse, mutect2, varscan2
- NUP153 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100020987; called by muse, mutect2, varscan2
- NUTM2F | c.919C>G p.P307A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV53555512; called by muse, mutect2, varscan2
- OAS2 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV60801234; called by muse, mutect2, varscan2
- OBP2B | c.132G>C p.R44S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV64402250; called by muse, mutect2, varscan2
- OBSCN | c.14612C>G p.S4871* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV52743559, COSV99480942; called by muse, mutect2, varscan2
- OGA | c.2086G>C p.D696H | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV63381004; called by muse, mutect2, varscan2
- OLFML2B | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV54194344; called by muse, mutect2, varscan2
- OR4E2 | c.778C>G p.R260G | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV57731422; called by muse, mutect2, varscan2
- OR51A7 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV63788058; called by muse, mutect2, varscan2
- OR5A1 | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV57375842; called by muse, mutect2, varscan2
- OR5AK2 | c.161G>C p.R54T | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV58803862; called by muse, mutect2, varscan2
- OR6B1 | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV68769807; called by muse, varscan2
- OR7G2 | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as COSV100560602, COSV59687665; called by muse, varscan2
- OR8J1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs752525289, COSV57316740; called by muse, mutect2, varscan2
- ORC4 | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as COSV51571916; called by muse, mutect2, varscan2
- OSGEPL1 | c.1202G>C p.G401A | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV51461812; called by muse, mutect2, varscan2
- OTOP3 | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60912324; called by muse, mutect2, varscan2
- OTUD4 | c.2651C>T p.S884F (on ENST00000447906 / NM_001366057.1; = p.S819F on NM_001102653.1) | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV71381477; called by muse, mutect2, varscan2
- OTUD7B | c.1870C>G p.Q624E | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV64915224; called by muse, mutect2, varscan2
- PA2G4 | c.795C>G p.F265L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV57567531; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1157C>T p.S386L (on ENST00000259318 / NM_001136562.3; = p.S617L on NM_007203.5) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV52173627; called by muse, mutect2, varscan2
- PANK1 | c.1378C>G p.L460V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV56806439; called by muse, mutect2, varscan2
- PARP1 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV64689363; called by muse, mutect2, varscan2
- PCDH10 | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV52087959; called by muse, mutect2, varscan2
- PCDH12 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.059); catalogued as COSV51519450; called by muse, mutect2, varscan2
- PCDHA11 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as rs782232980, COSV56503254; called by muse, mutect2
- PCDHGA7 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.035); catalogued as rs763555331, COSV53903729, COSV53920818; called by muse, mutect2, varscan2
- PDAP1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV56117190, COSV56117855; called by muse, mutect2, varscan2
- PDIA5 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV60247236; called by muse, mutect2, varscan2
- PDPR | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV55349315; called by muse, mutect2, varscan2
- PDZK1 | c.1523C>G p.S508* | Nonsense Mutation (SNP) | VAF 43/186 reads (23%) | catalogued as COSV100572551; called by muse, mutect2, varscan2
- PGBD2 | c.1754G>A p.C585Y | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61399648; called by muse, mutect2, varscan2
- PGBD4 | c.1467G>C p.L489F | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as COSV56626544; called by muse, mutect2, varscan2
- PHF12 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52018198; called by muse, mutect2, varscan2
- PI4KA | c.1153C>G p.L385V | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); catalogued as COSV55404973; called by muse, varscan2
- PIWIL1 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV55344391; called by muse, mutect2, varscan2
- PKD1L1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV56958541; called by muse, mutect2, varscan2
- PKNOX1 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); catalogued as COSV52334289; called by muse, mutect2, varscan2
- PLA2G4D | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV51819251, COSV99299316; called by muse, mutect2, varscan2
- PLCG2 | c.2085C>G p.I695M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV63867607; called by muse, mutect2, varscan2
- PLD5 | c.301G>A p.E101K (on ENST00000442594; = p.E39K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV59156499; called by muse, mutect2, varscan2
- PLG | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as COSV51980836; called by muse, mutect2, varscan2
- PLTP | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.49); PolyPhen benign (0.076); catalogued as COSV51940757, COSV51941356; called by muse, mutect2, varscan2
- PLVAP | c.1179+1G>C p.X393_splice | Splice Site (SNP) | VAF 22/54 reads (41%) | catalogued as rs111831522, COSV53083677; called by muse, varscan2
- PLXNA3 | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as COSV63753262; called by muse, mutect2, varscan2
- PLXNB1 | c.5135G>A p.R1712Q | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181346044, COSV56486823, COSV56493185; called by muse, mutect2, varscan2
- PML | c.1228C>G p.P410A | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV51442565, COSV99167077; called by muse, mutect2, varscan2
- PMS2 | c.2269G>C p.E757Q | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV56219781; called by muse, mutect2, varscan2
- PNMA3 | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV64721819; called by muse, mutect2
- POGZ | c.3225C>G p.F1075L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51850379; called by muse, mutect2, varscan2
- POLR1B | c.2684G>T p.R895I | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); catalogued as COSV54495067; called by muse, mutect2, varscan2
- POTEM | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 53/432 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs1457230726, COSV69152143; called by muse, mutect2, varscan2
- PPARD | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.826); catalogued as COSV100282967, COSV100283420; called by muse, mutect2
- PPAT | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV51703054; called by muse, mutect2, varscan2
- PPIG | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV53641427; called by muse, mutect2, varscan2
- PPL | c.2404G>C p.E802Q | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62044778; called by muse, mutect2, varscan2
- PPM1H | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV57370677; called by muse, mutect2, varscan2
- PPM1M | c.385G>A p.D129N (on ENST00000296487; = p.D290N on NM_144641.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs773636737, COSV56598794; called by muse, mutect2, varscan2
- PPP2R5D | c.423C>G p.F141L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.06); catalogued as COSV57839160; called by muse, mutect2, varscan2
- PRC1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV62694223; called by muse, mutect2, varscan2
- PRDM2 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV99342939; called by muse, mutect2, varscan2
- PREPL | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs776058554, COSV53215152; called by muse, mutect2, varscan2
- PRKCD | c.609G>C p.K203N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.811); catalogued as COSV57846859; called by muse, mutect2, varscan2
- PRKDC | c.179C>A p.S60Y | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV50621366; called by muse, mutect2, varscan2
- PRPF38B | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV64223491; called by muse, mutect2, varscan2
- PRRC2A | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as rs763007534, COSV65685219; called by muse, mutect2, varscan2
- PRRC2C | c.7451C>G p.S2484C (on ENST00000367742; = p.S2482C on NM_015172.4) | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58901557; called by muse, mutect2, varscan2
- PRRG1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV66156775; called by muse, mutect2, varscan2
- PRRG1 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66156780; called by muse, mutect2, varscan2
- PSMA3 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.984); catalogued as COSV53616416; called by muse, mutect2, varscan2
- PSMD4 | c.935C>G p.S312* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as COSV64393073; called by muse, mutect2, varscan2
- PTCRA | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV58975311; called by muse, mutect2, varscan2
- PTGER2 | c.844-1G>A p.X282_splice | Splice Site (SNP) | VAF 37/110 reads (34%) | catalogued as COSV55418175; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.343G>C p.E115Q (on ENST00000421990 / NM_001136042.2; = p.E97Q on NM_025267.3) | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.929); catalogued as COSV64181900; called by muse, mutect2, varscan2
- PTPRC | c.3463G>T p.E1155* | Nonsense Mutation (SNP) | VAF 23/87 reads (26%) | catalogued as COSV61406868; called by muse, mutect2, varscan2
- PTPRG | c.3943C>G p.Q1315E | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs1219559048, COSV55629580; called by muse, mutect2, varscan2
- PTPRT | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61962223, COSV61980073; called by muse, varscan2
- PYHIN1 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 36/122 reads (30%) | catalogued as COSV100932431, COSV63721392; called by muse, mutect2, varscan2
- PYROXD1 | c.1004G>C p.G335A | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.07); catalogued as COSV53708202; called by muse, mutect2, varscan2
- PZP | c.470G>C p.R157P | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV54354958, COSV54365221; called by muse, mutect2, varscan2
- QSER1 | c.283C>G p.H95D (on ENST00000399302; = p.H224D on NM_001076786.3) | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs777497808, COSV67899604; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.521); catalogued as COSV54758323; called by muse, mutect2, varscan2
- RAB6A | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60177607; called by muse, mutect2, varscan2
- RALGAPA1 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV51877083; called by muse, mutect2, varscan2
- RALGDS | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100924462; called by muse, mutect2, varscan2
- RARB | c.881G>A p.R294Q (on ENST00000383772 / NM_001290216.2; = p.R287Q on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV51968886; called by muse, mutect2, varscan2
- RBM15 | c.2246C>G p.S749C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs1478439535, COSV63923084; called by muse, mutect2, varscan2
- RBM8A | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV57161936; called by muse, mutect2, varscan2
- RBSN | c.434G>C p.R145P | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99515589; called by muse, mutect2, varscan2
- RELN | c.5144C>G p.S1715* | Nonsense Mutation (SNP) | VAF 32/77 reads (42%) | catalogued as COSV58986995; called by muse, mutect2, varscan2
- REST | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58359431; called by muse, mutect2, varscan2
- RET | c.1875C>G p.I625M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.235); catalogued as COSV60687480; called by muse, mutect2, varscan2
- RHBDF2 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV57419512; called by muse, mutect2
- RHOA | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV69041730; called by muse, mutect2, varscan2
- RIC1 | c.3885G>C p.Q1295H | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs374147809; called by muse, mutect2, varscan2
- RICTOR | c.2425C>T p.L809F | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV57117463; called by muse, mutect2, varscan2
- RIF1 | c.7030C>T p.L2344F | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54612711; called by muse, mutect2, varscan2
- RIMS1 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV53438714, COSV53440385; called by muse, mutect2, varscan2
- RIOX1 | c.1001C>G p.S334W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58373555; called by muse, mutect2, varscan2
- RMDN2 | c.706G>C p.E236Q (on ENST00000354545 / NM_001322212.2; = p.E414Q on NM_144713.5) | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as COSV52222408, COSV52223926; called by muse, mutect2, varscan2
- RMDN3 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV53023212; called by muse, mutect2, varscan2
- RNLS | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV59290720, COSV59295144; called by muse, mutect2, varscan2
- ROBO1 | c.2855G>A p.G952E | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV71391999; called by muse, mutect2, varscan2
- ROBO2 | c.1422G>C p.Q474H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.275); catalogued as rs1316651009, COSV100166873, COSV59898286, COSV59922203; called by muse, mutect2, varscan2
- RPGRIP1 | c.1885G>C p.E629Q | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52845306, COSV52845587; called by muse, mutect2, varscan2
- RPS6KC1 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV65297338; called by muse, mutect2, varscan2
- RSBN1L | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV58506432; called by muse, mutect2, varscan2
- RSPH14 | c.76C>G p.R26G | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1479164076, COSV53266880; called by muse, mutect2, varscan2
- RUFY2 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61190508; called by muse, mutect2, varscan2
- RUNX2 | c.1019C>A p.S340* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV61838969; called by muse, mutect2, varscan2
- RXRG | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 36/129 reads (28%) | catalogued as COSV63231504; called by muse, mutect2, varscan2
- RYR1 | c.8427C>G p.I2809M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as COSV62089823; called by muse, mutect2, varscan2
- RYR2 | c.12464C>A p.S4155Y | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as CM1310852, COSV63664208; called by muse, mutect2, varscan2
- RYR3 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66778926; called by muse, mutect2, varscan2
- SACS | c.10207G>A p.D3403N | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV66534971; called by muse, mutect2, varscan2
- SAMD15 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV53625346; called by muse, mutect2, varscan2
- SAMD4A | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV51877041; called by muse, mutect2, varscan2
- SAMSN1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53467853; called by muse, mutect2, varscan2
- SCN10A | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs201955990; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SCN11A | c.2147C>G p.S716* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV56566201; called by muse, mutect2, varscan2
- SCYL2 | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.095); catalogued as COSV62567693; called by muse, mutect2, varscan2
- SCYL3 | c.1122G>C p.K374N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV63044698; called by muse, mutect2, varscan2
- SDE2 | c.1175C>G p.S392C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV55249903; called by muse, mutect2, varscan2
- SECISBP2L | c.698C>G p.S233* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV55932845; called by muse, mutect2, varscan2
- SELENOI | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53142998; called by muse, mutect2, varscan2
- SEMA4D | c.1630C>G p.Q544E | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59391203; called by muse, mutect2, varscan2
- SEMA6A | c.1751C>A p.P584H | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV56709453; called by muse, mutect2, varscan2
- SENP1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 217/382 reads (57%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV50286689, COSV99137003; called by muse, varscan2
- SENP1 | c.507G>C p.L169F | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV50286694, COSV99136877; called by muse, mutect2, varscan2
- SERAC1 | c.1829-1G>C p.X610_splice | Splice Site (SNP) | VAF 33/76 reads (43%) | catalogued as COSV65595521; called by muse, mutect2, varscan2
- SETD2 | c.1853C>G p.S618* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as rs750437096, COSV57430858; called by muse, mutect2, varscan2
- SETD2 | c.1760C>G p.S587C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); catalogued as COSV100339445, COSV57430882; called by muse, mutect2, varscan2
- SGCG | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT tolerated (0.35); PolyPhen benign (0.191); catalogued as rs768134426, CM002106, COSV54556424; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3KBP1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV65639354; called by muse, mutect2, varscan2
- SH3PXD2A | c.2505G>C p.K835N (on ENST00000369774 / NM_001365079.1; = p.K807N on NM_014631.2) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60115787; called by muse, mutect2, varscan2
- SHE | c.1309C>G p.Q437E | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV59070840; called by muse, mutect2, varscan2
- SIGLEC5 | c.1517C>G p.P506R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99708018; called by muse, mutect2
- SIN3A | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64581884; called by muse, mutect2, varscan2
- SKAP2 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61721561; called by muse, mutect2, varscan2
- SKIDA1 | c.1423C>G p.P475A | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV71610455; called by muse, varscan2
- SLC17A2 | c.778C>G p.P260A | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as COSV55350438; called by muse, mutect2, varscan2
- SLC17A5 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs748755467, COSV63287073; called by muse, mutect2, varscan2
- SLC24A3 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV60112620; called by muse, mutect2, varscan2
- SLC38A1 | c.1332G>C p.Q444H | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV101284292, COSV67062941; called by muse, mutect2, varscan2
- SLC38A5 | c.1350C>A p.F450L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.327); catalogued as COSV58333342, COSV58333443; called by muse, mutect2, varscan2
- SLC38A6 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50781139; called by muse, mutect2, varscan2
- SLC4A1AP | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV58133732; called by muse, mutect2, varscan2
- SLC9A2 | c.2306C>G p.S769C | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV52128945, COSV52138815; called by muse, mutect2, varscan2
- SLCO1B1 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs758561937, COSV57007432; called by muse, mutect2, varscan2
- SLFN13 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV53192323; called by muse, mutect2, varscan2
- SMAD4 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 38/53 reads (72%) | catalogued as COSV61684971, COSV61693968; called by muse, mutect2, varscan2
- SMARCA1 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV64410961; called by muse, mutect2, varscan2
- SMARCA4 | c.3426C>A p.F1142L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60787200, COSV60795410; called by muse, mutect2, varscan2
- SMNDC1 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV63651539; called by muse, mutect2, varscan2
- SMO | c.1244G>C p.G415A | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.739); catalogued as COSV50824439; called by muse, mutect2, varscan2
- SNAP91 | c.1309G>C p.V437L | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52115970; called by muse, mutect2, varscan2
- SND1 | c.2149G>T p.D717Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as COSV61235509; called by muse, mutect2, varscan2
- SNRNP48 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60938721; called by muse, mutect2, varscan2
- SNRPG | c.45G>C p.K15N | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV55476139; called by muse, mutect2, varscan2
- SOX5 | c.1328G>C p.R443T | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as COSV58619498, COSV58633791; called by muse, mutect2, varscan2
- SPATA31D1 | c.3389G>C p.R1130T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.168); catalogued as COSV61193041, COSV61196549; called by muse, mutect2, varscan2
- SPDEF | c.573C>A p.F191L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV100927846; called by muse, mutect2
- SPDEF | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.797); catalogued as rs755931546, COSV65000612; called by muse, mutect2, varscan2
- SPESP1 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV52985229; called by muse, mutect2, varscan2
- SPHKAP | c.4096G>A p.E1366K | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV60869373; called by muse, mutect2, varscan2
- SPON1 | c.651G>C p.E217D | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.726); catalogued as COSV59957831; called by muse, mutect2, varscan2
- SPRY2 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1315863703, COSV101001678, COSV65701213; called by muse, mutect2, varscan2
- SPRYD7 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs763469553, COSV62523644; called by muse, mutect2, varscan2
- ST14 | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV53831576; called by muse, mutect2, varscan2
- STAG1 | c.957G>A p.M319I | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV52602223; called by muse, varscan2
- STAG1 | c.923G>C p.R308T | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52602233; called by muse, varscan2
- STEAP2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV55289287; called by muse, mutect2, varscan2
- STON1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV59126576; called by muse, mutect2, varscan2
- STPG4 | c.113G>C p.R38T | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54277997; called by muse, mutect2, varscan2
- STX17 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as COSV52282332; called by muse, mutect2, varscan2
- SUGP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53233679, COSV99448717; called by muse, mutect2, varscan2
- SVEP1 | c.10244C>G p.S3415* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as COSV52836062; called by muse, mutect2, varscan2
- SYCP2L | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV51650152; called by muse, mutect2, varscan2
- SYDE1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54618058; called by muse, mutect2, varscan2
- SYNE2 | c.17674G>C p.E5892Q | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV59940492; called by muse, mutect2, varscan2
- SYT16 | c.347C>G p.S116* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV70855121; called by muse, mutect2, varscan2
- SYTL3 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV51908214, COSV51911941; called by muse, mutect2, varscan2
- TAX1BP3 | c.160-1G>C p.X54_splice | Splice Site (SNP) | VAF 17/38 reads (45%) | catalogued as COSV50264964; called by muse, mutect2, varscan2
- TBC1D15 | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV59847484; called by muse, mutect2, varscan2
- TBC1D32 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51536830; called by muse, mutect2, varscan2
- TBC1D5 | c.819G>C p.Q273H | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV53749871; called by muse, mutect2, varscan2
- TCF20 | c.2116C>T p.R706C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.854); catalogued as rs760478206, COSV59488619; called by muse, mutect2, varscan2
- TCHH | c.3073G>A p.E1025K | Missense Mutation (SNP) | VAF 139/516 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV64273075; called by muse, mutect2, varscan2
- TDP2 | c.156G>A p.W52* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV57763496; called by muse, mutect2, varscan2
- TDRD6 | c.2989G>A p.D997N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.214); catalogued as COSV60174013; called by muse, mutect2, varscan2
- TEKT5 | c.750G>C p.E250D | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV51586768; called by muse, mutect2, varscan2
- TESK2 | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100517254, COSV59149476, COSV59156710; called by muse, mutect2, varscan2
- TEX15 | c.7501G>C p.D2501H (on ENST00000256246; = p.D2884H on NM_001350162.2) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as COSV56342058, COSV99821523; called by muse, mutect2, varscan2
- TEX15 | c.4958G>C p.R1653T (on ENST00000256246; = p.R2036T on NM_001350162.2) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV56342071, COSV99821441; called by muse, mutect2, varscan2
- THEM5 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV64312726; called by muse, mutect2, varscan2
- THSD7B | c.4055G>C p.G1352A (on ENST00000272643; = p.G1350A on NM_001316349.2) | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.492); catalogued as COSV55657367, COSV55700577, COSV55721229; called by muse, mutect2, varscan2
- TIAM2 | c.1735C>G p.P579A | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59689870, COSV59697882; called by muse, mutect2, varscan2
- TJP1 | c.4102G>C p.E1368Q | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.608); catalogued as COSV100633269, COSV62046597; called by muse, mutect2
- TLE3 | c.328_330del p.R110del | In Frame Del (DEL) | VAF 13/84 reads (15%) | catalogued as COSV58166737; called by mutect2, pindel, varscan2
- TLR4 | c.162C>G p.F54L (on ENST00000355622 / NM_138554.5; = p.F14L on NM_003266.4) | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV62922469; called by muse, mutect2, varscan2
- TM9SF3 | c.836G>C p.G279A | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64456665; called by muse, mutect2, varscan2
- TMEM135 | c.809G>A p.C270Y | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59696625; called by muse, mutect2, varscan2
- TMEM17 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV59022385; called by muse, mutect2, varscan2
- TMEM53 | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV62636927; called by muse, mutect2, varscan2
- TMEM80 | c.248G>A p.R83Q (on ENST00000526170 / NM_001276274.1; = p.R145Q on NM_174940.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as rs754819477, COSV68773725; called by muse, mutect2, varscan2
- TMF1 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV68373590; called by muse, mutect2, varscan2
- TMPO | c.295dup p.T99Nfs*2 | Frame Shift Ins (INS) | VAF 32/108 reads (30%) | catalogued as rs770800449; called by mutect2, varscan2
- TNIK | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 91/252 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV52674481; called by muse, mutect2, varscan2
- TNKS2 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 96/242 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV65414741; called by muse, mutect2, varscan2
- TNNI3 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs727504268, COSV52570425; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TOB1 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 52/776 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52150312, COSV99278966; called by muse, mutect2
- TOB1 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99278967; called by muse, mutect2
- TP53BP2 | c.808G>A p.D270N (on ENST00000343537 / NM_001031685.3; = p.D141N on NM_005426.2) | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV59066572; called by muse, mutect2, varscan2
- TPR | c.5950G>A p.E1984K | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); catalogued as COSV66599554; called by muse, mutect2, varscan2
- TRAK2 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs917824755, COSV60270521; called by muse, varscan2
- TRAPPC9 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV66893181; called by muse, mutect2, varscan2
- TRIM33 | c.2929G>T p.E977* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as COSV61820927; called by muse, mutect2, varscan2
- TRIM49 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV61670316; called by muse, mutect2, varscan2
- TRIP11 | c.720G>C p.Q240H | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50913710; called by muse, mutect2, varscan2
- TRPM3 | c.4933G>A p.E1645K (on ENST00000357533 / NM_001366142.2; = p.E1500K on NM_020952.6) | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.034); catalogued as COSV62580446; called by muse, mutect2, varscan2
- TSHZ3 | c.2432C>T p.T811M | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as rs200018669, COSV53665245; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV54648300; called by muse, mutect2, varscan2
- TTN | c.82447G>A p.G27483S (on ENST00000591111; = p.G20059S on NM_003319.4) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | PolyPhen probably damaging (0.999); catalogued as COSV59901502; called by muse, mutect2, varscan2
- TTN | c.59593G>A p.E19865K (on ENST00000591111; = p.E12441K on NM_003319.4) | Missense Mutation (SNP) | VAF 110/284 reads (39%) | PolyPhen benign (0.022); catalogued as COSV59901545; called by muse, mutect2, varscan2
- TTN | c.35571G>C p.K11857N (on ENST00000591111; = p.K4433N on NM_003319.4) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | PolyPhen probably damaging (0.994); catalogued as COSV59901574; called by muse, mutect2, varscan2
- TTN | c.14362G>C p.E4788Q (on ENST00000591111; = p.E3861Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | PolyPhen possibly damaging (0.892); catalogued as COSV59901592, COSV59968608, COSV59979253; called by muse, mutect2, varscan2
- TTN | c.5255G>A p.R1752H (on ENST00000591111; = p.R1706H on NM_003319.4) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | PolyPhen probably damaging (0.998); catalogued as rs150737838, COSV59901601; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TUBB | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.403); catalogued as COSV58357301; called by muse, mutect2, varscan2
- TXK | c.582-1G>A p.X194_splice | Splice Site (SNP) | VAF 32/76 reads (42%) | catalogued as COSV51912675; called by muse, mutect2, varscan2
- TXNDC2 | c.1475C>T p.A492V (on ENST00000306084 / NM_001098529.2; = p.A425V on NM_032243.6) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV60152160; called by muse, mutect2, varscan2
- TXNDC5 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.175); catalogued as COSV65729948; called by muse, mutect2, varscan2
- UBQLN1 | c.1615C>G p.Q539E | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV57406628; called by muse, mutect2, varscan2
- UBR2 | c.5124C>T p.L1708= | Splice Region (SNP) | VAF 48/109 reads (44%) | catalogued as COSV65748888; called by muse, mutect2, varscan2
- UBR3 | c.3538G>C p.E1180Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55844810; called by muse, mutect2, varscan2
- UCHL5 | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs1302564487, COSV66485745; called by muse, mutect2, varscan2
- UGGT1 | c.4078G>T p.D1360Y | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52132687; called by muse, mutect2, varscan2
- UGT2B17 | c.1057C>G p.R353G | Missense Mutation (SNP) | VAF 55/70 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58500908; called by muse, mutect2, varscan2
- UNC13C | c.3874G>A p.D1292N | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52845719, COSV99513646; called by muse, mutect2, varscan2
- URB2 | c.2398C>G p.L800V | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV50981592; called by muse, mutect2, varscan2
- USF3 | c.3466G>A p.D1156N | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV57070096; called by muse, mutect2, varscan2
- USH2A | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56331274; called by muse, mutect2, varscan2
- USP19 | c.3647C>G p.S1216C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV67349110; called by muse, mutect2, varscan2
- USP24 | c.7739G>A p.G2580E | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs764118354, COSV53762383; called by muse, mutect2, varscan2
- USP4 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.633); catalogued as COSV55535018, COSV99649267; called by muse, mutect2, varscan2
- UTS2B | c.4A>G p.N2D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1233830073, COSV100484398; called by muse, mutect2
- VANGL2 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63604046; called by muse, mutect2, varscan2
- VCAN | c.5834C>T p.S1945F | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV54097546; called by muse, mutect2, varscan2
- VCAN | c.7237G>A p.E2413K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.59); PolyPhen benign (0.105); catalogued as COSV54096458, COSV54100245, COSV54103967; called by muse, mutect2, varscan2
- VNN2 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58471584, COSV58473810; called by muse, mutect2, varscan2
- VPS13A | c.5404C>G p.L1802V | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV62425540; called by muse, mutect2, varscan2
- VPS26A | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV54967023; called by muse, mutect2, varscan2
- VPS39 | c.691G>C p.E231Q (on ENST00000348544 / NM_001301138.2; = p.E220Q on NM_015289.5) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.599); catalogued as COSV58787875; called by muse, mutect2, varscan2
- VWA7 | c.1540G>C p.G514R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.181); catalogued as COSV65172424; called by muse, mutect2
- WASHC2C | c.3529G>C p.E1177Q (on ENST00000336378; = p.E1156Q on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as rs1389142717; called by muse, mutect2, varscan2
- WASL | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56132411; called by muse, mutect2, varscan2
- WDR44 | c.1973G>C p.R658T | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV54160573; called by muse, mutect2, varscan2
- WDR75 | c.587C>G p.S196* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV59104779; called by muse, mutect2, varscan2
- WDR93 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.731); catalogued as COSV51530597; called by muse, mutect2, varscan2
- WNK3 | c.3713G>T p.S1238I | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV63612222; called by muse, mutect2, varscan2
- XAB2 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs745761079, COSV60696810; called by muse, mutect2, varscan2
- XIRP2 | c.3964C>T p.R1322* (on ENST00000628543; = p.R1497* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as rs202158141; called by muse, mutect2, varscan2
- XKR6 | c.840G>A p.M280I | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs984511189, COSV58654520; called by muse, mutect2, varscan2
- XPO1 | c.1625C>G p.S542* | Nonsense Mutation (SNP) | VAF 31/78 reads (40%) | catalogued as COSV68944715; called by muse, mutect2, varscan2
- ZBTB9 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV67701795; called by muse, mutect2, varscan2
- ZCWPW2 | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1324204524, COSV101075434; called by muse, mutect2
- ZDBF2 | c.2129C>G p.S710C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65622188; called by muse, mutect2, varscan2
- ZDBF2 | c.3584G>C p.C1195S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV65622196; called by muse, mutect2, varscan2
- ZDBF2 | c.6112G>C p.D2038H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV65622204, COSV65624305; called by muse, mutect2, varscan2
- ZEB1 | c.530G>C p.R177T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58037049; called by muse, mutect2, varscan2
- ZFYVE1 | c.312G>C p.Q104H | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV59609868; called by muse, mutect2, varscan2
- ZFYVE26 | c.7243G>C p.E2415Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as COSV61324824; called by muse, mutect2, varscan2
- ZHX2 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58710500; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2156G>A p.G719E | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.077); catalogued as rs1271214955, COSV60155663; called by muse, mutect2, varscan2
- ZNF106 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as rs147629444; called by muse, mutect2, varscan2
- ZNF17 | c.1508G>C p.C503S | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56920775; called by muse, mutect2, varscan2
- ZNF22 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as COSV53584717, COSV53585058; called by muse, mutect2, varscan2
- ZNF322 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV70651851; called by muse, mutect2, varscan2
- ZNF324B | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.074); catalogued as COSV60740652, COSV60741806; called by muse, mutect2, varscan2
- ZNF33A | c.769G>A p.D257N (on ENST00000458705 / NM_006974.3; = p.D258N on NM_006954.2) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.922); catalogued as COSV56723206, COSV56727483; called by muse, mutect2, varscan2
- ZNF33A | c.1384C>G p.H462D (on ENST00000458705 / NM_006974.3; = p.H463D on NM_006954.2) | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56723219; called by muse, mutect2, varscan2
- ZNF382 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs746468500, COSV99498179; called by muse, mutect2
- ZNF407 | c.6379G>C p.E2127Q | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV55243650; called by muse, mutect2, varscan2
- ZNF423 | c.1396G>A p.E466K (on ENST00000563137 / NM_001379286.1; = p.E458K on NM_015069.4) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs1291466200, COSV52178344; called by muse, mutect2, varscan2
- ZNF430 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV55108156; called by muse, mutect2, varscan2
- ZNF441 | c.368G>C p.R123T | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV63539139; called by muse, mutect2, varscan2
- ZNF451 | c.3140-1G>C p.X1047_splice (on ENST00000370706 / NM_001031623.3; = p.X999_splice on NM_015555.2) | Splice Site (SNP) | VAF 46/129 reads (36%) | catalogued as COSV62596629; called by muse, mutect2, varscan2
- ZNF462 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV52931026; called by muse, mutect2, varscan2
- ZNF501 | c.123G>C p.Q41H | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV68516174; called by muse, mutect2, varscan2
- ZNF565 | c.1594G>A p.E532K (on ENST00000355114; = p.E492K on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV58410351; called by muse, mutect2, varscan2
- ZNF586 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV66972144; called by muse, mutect2, varscan2
- ZNF626 | c.479C>G p.S160* | Nonsense Mutation (SNP) | VAF 115/305 reads (38%) | catalogued as COSV74128989; called by muse, mutect2, varscan2
- ZNF676 | c.325G>C p.E109Q (on ENST00000650058; = p.E77Q on NM_001001411.3) | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs756136777, COSV101236373, COSV68093109; called by muse, mutect2, varscan2
- ZNF695 | c.1043G>C p.G348A | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60584758; called by muse, mutect2, varscan2
- ZNF707 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV62311012; called by muse, mutect2, varscan2
- ZNF83 | c.205C>G p.H69D | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs1394460858, COSV56528588; called by muse, mutect2, varscan2
- ZNRF3 | c.810G>C p.K270N (on ENST00000544604 / NM_001206998.2; = p.K170N on NM_032173.3) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV60431543; called by muse, mutect2, varscan2
- KIR2DL4 | c.673C>G p.P225A (on ENST00000396284; = p.P186A on NM_001080770.2) | Missense Mutation (SNP) | VAF 141/379 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MLLT10 | c.693_694del p.K234Ifs*2 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by pindel, varscan2
- PRMT5 | c.893_901del p.E298_F300del | In Frame Del (DEL) | VAF 24/85 reads (28%) | called by mutect2, pindel, varscan2
- TGM2 | c.564del p.I189Sfs*2 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | called by mutect2, pindel, varscan2
- THAP12 | c.812_814del p.A271del | In Frame Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- TMEM167B | c.96del p.W33Gfs*18 | Frame Shift Del (DEL) | VAF 88/281 reads (31%) | called by mutect2, pindel, varscan2
- TTN | c.63507del p.G21170Vfs*13 (on ENST00000591111; = p.G13746Vfs*13 on NM_003319.4) | Frame Shift Del (DEL) | VAF 44/147 reads (30%) | called by mutect2, pindel, varscan2
- ABCB5 | c.687C>T p.I229= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV51703374; called by muse, mutect2, varscan2
- ABCC1 | c.114C>G p.L38= | Silent (SNP) | VAF 138/323 reads (43%) | catalogued as COSV100580200, COSV60680828; called by muse, mutect2, varscan2
- ACCS | c.975C>T p.F325= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs760361959, COSV55457228; called by muse, mutect2, varscan2
- ADGRF5 | c.2646C>G p.V882= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV51930120; called by muse, mutect2, varscan2
- AIP | c.12C>T p.I4= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV54159819; called by muse, mutect2, varscan2
- ALOX12 | c.1086G>A p.L362= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV52348646; called by muse, mutect2, varscan2
- AMBRA1 | c.1560G>C p.L520= (on ENST00000458649 / NM_001367468.1; = p.L430= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV54049059, COSV54050046; called by muse, mutect2, varscan2
- ANKRD27 | c.1434C>G p.L478= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV60129093; called by muse, mutect2, varscan2
- ARAP3 | c.2187C>G p.L729= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV53348856; called by muse, mutect2, varscan2
- ARHGEF18 | c.2070C>G p.V690= (on ENST00000359920 / NM_001130955.2; = p.V586= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV60467183; called by muse, mutect2, varscan2
- ARMC4 | c.2586C>T p.L862= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV59456735, COSV59462668; called by muse, mutect2, varscan2
- ASNS | c.645C>G p.L215= | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as COSV51550400; called by muse, mutect2, varscan2
- ASPM | c.8808C>T p.T2936= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV54125097; called by muse, mutect2, varscan2
- ATOH7 | c.333C>G p.L111= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV65447593; called by muse, mutect2, varscan2
- BAAT | c.477C>T p.L159= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs774541981, COSV52287311; called by muse, mutect2, varscan2
- BAZ1A | c.1248G>A p.V416= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV62409081, COSV62409237; called by muse, mutect2, varscan2
- CA11 | c.762C>G p.L254= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1172725648, COSV50032751; called by muse, mutect2, varscan2
- CCDC62 | c.1293C>T p.H431= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV53430858; called by muse, mutect2, varscan2
- CCND3 | c.765C>T p.L255= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV57827837; called by muse, mutect2, varscan2
- CD22 | c.471C>T p.V157= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV50049708; called by muse, mutect2, varscan2
- CDK10 | c.321G>A p.G107= (on ENST00000353379 / NM_052988.5; = p.G36= on NM_052987.4) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs754188486, COSV57045893; called by muse, mutect2, varscan2
- CELSR2 | c.2742G>C p.V914= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV54767211; called by muse, mutect2, varscan2
- CELSR2 | c.4920C>G p.L1640= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV54767219, COSV54774792; called by muse, mutect2, varscan2
- CHAF1A | c.522G>A p.E174= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV56670428; called by muse, mutect2, varscan2
- CHP1 | c.465C>T p.I155= | Silent (SNP) | VAF 58/134 reads (43%) | catalogued as rs1347617441, COSV58156483; called by muse, mutect2, varscan2
- CMAS | c.738G>T p.V246= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV57556051; called by muse, mutect2, varscan2
- CNTFR | c.480C>G p.L160= | Silent (SNP) | VAF 34/52 reads (65%) | catalogued as COSV63633205, COSV63633534; called by muse, mutect2, varscan2
- COG8 | c.765C>G p.L255= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV54741748; called by muse, mutect2, varscan2
- COL22A1 | c.4152G>C p.G1384= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV57324780; called by muse, mutect2, varscan2
- COL6A3 | c.2515C>T p.L839= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV55080526; called by muse, mutect2, varscan2
- COQ9 | c.382C>T p.L128= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV52645081; called by muse, mutect2, varscan2
- CTSV | c.975C>T p.I325= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as rs754024516, COSV52344091; called by muse, mutect2, varscan2
- CWH43 | c.1158C>T p.F386= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as COSV56936164; called by muse, mutect2, varscan2
- CYP1A2 | c.495G>C p.V165= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV59659090; called by muse, mutect2, varscan2
- DAAM1 | c.2784C>T p.V928= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs1354249718, COSV62834272; called by muse, mutect2, varscan2
- DBH | c.531C>T p.F177= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1397344602, COSV55039766; called by muse, mutect2, varscan2
- DENND2C | c.483C>G p.L161= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs748488239, COSV67921194; called by muse, mutect2, varscan2
- DENND4A | c.2535C>G p.A845= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV71265230; called by muse, mutect2, varscan2
- DEPDC5 | c.3711G>C p.R1237= (on ENST00000400246; = p.R1306= on NM_014662.5) | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV56691593; called by muse, mutect2, varscan2
- DMD | c.9348G>A p.Q3116= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV58893306; called by muse, mutect2, varscan2
- DMXL2 | c.5955C>T p.A1985= | Silent (SNP) | VAF 55/154 reads (36%) | catalogued as COSV51841167; called by muse, mutect2, varscan2
- DNAH9 | c.10392C>G p.L3464= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as COSV52335513; called by muse, mutect2, varscan2
- DNMT3A | c.1815C>T p.L605= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV53040009; called by muse, mutect2, varscan2
- DOCK5 | c.684C>T p.F228= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as COSV52396448; called by muse, mutect2, varscan2
198 further variants in this file (0 protein-altering or splice-affecting, 178 silent, 20 other) are not listed here.
